Somatic mutation profile of tumor specimen TCGA-2L-AAQI-01A (aliquot TCGA-2L-AAQI-01A-12D-A397-08) from TCGA case TCGA-2L-AAQI, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 66.8 years (24,381 days).
Specimen TCGA-2L-AAQI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14e947ca-d44a-4bf3-9b72-313fd89ad7b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2L-AAQI-11A (Solid Tissue Normal), aliquot TCGA-2L-AAQI-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1b8d611-636f-4f87-adfe-1457c6805d86

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 4, Intron 1, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 41/345 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 28/196 reads (14%) | catalogued as COSV100710901, COSV61276249, COSV61280837; called by muse, mutect2, varscan2
- ADGRD1 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs200971352, COSV55440249; called by muse, mutect2, varscan2
- CCDC8 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 112/767 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV56772127; called by muse, mutect2, varscan2
- CNGA4 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1564877770, COSV66004968; called by muse, mutect2, varscan2
- CNTN1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 71/520 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191888454, COSV61636657; called by muse, mutect2, varscan2
- COL22A1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.788); catalogued as rs1359249026, COSV57323312; called by muse, mutect2
- DGKI | c.2743C>T p.H915Y | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs1253594034, COSV99934384; called by muse, mutect2, varscan2
- DIAPH1 | c.3103C>G p.L1035V | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV99526535; called by muse, mutect2, varscan2
- DIXDC1 | c.910G>A p.G304R (on ENST00000440460 / NM_001037954.4; = p.G93R on NM_033425.4) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.988); catalogued as COSV100180225, COSV100180242; called by muse, mutect2
- DNMT3B | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 71/512 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs201657518, COSV99141415; called by muse, mutect2, varscan2
- IKZF2 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 37/333 reads (11%) | catalogued as rs867974779, COSV59577002; called by muse, mutect2, varscan2
- KDM6A | c.564+2T>A p.X188_splice | Splice Site (SNP) | VAF 95/404 reads (24%) | catalogued as COSV100938175; called by muse, mutect2, varscan2
- KHDRBS2 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV99833570; called by muse, mutect2
- KRT6C | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1314732181, COSV99359965; called by muse, mutect2, varscan2
- LGALS3BP | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1337105288, COSV99431643; called by muse, mutect2, varscan2
- LILRB1 | c.964C>A p.P322T (on ENST00000427581; = p.P286T on NM_006669.6) | Missense Mutation (SNP) | VAF 25/450 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.88); catalogued as COSV100207284, COSV61116201; called by muse, mutect2
- MAP3K21 | c.2172T>G p.Y724* | Nonsense Mutation (SNP) | VAF 43/352 reads (12%) | catalogued as COSV100786102; called by muse, mutect2, varscan2
- MAST1 | c.1254G>C p.Q418H | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99262889; called by muse, mutect2
- MED12L | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs865957327, COSV99853050; called by muse, mutect2, varscan2
- MOSPD3 | c.513C>T p.H171= | Splice Region (SNP) | VAF 27/224 reads (12%) | catalogued as COSV99774938; called by muse, mutect2, varscan2
- NAGPA | c.1111G>T p.G371* | Nonsense Mutation (SNP) | VAF 25/214 reads (12%) | catalogued as COSV100392903; called by muse, mutect2, varscan2
- NHLH1 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV57483766; called by muse, mutect2, varscan2
- PAXBP1 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs141072916; called by muse, mutect2, varscan2
- RP1L1 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 87/602 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV101223223; called by muse, mutect2, varscan2
- SIRPB1 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs750300863, COSV53537498, COSV53540151; called by muse, mutect2, varscan2
- TEX2 | c.1219T>G p.L407V | Missense Mutation (SNP) | VAF 93/667 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as COSV99367090; called by muse, mutect2, varscan2
- TP53 | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRGV5 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- CACNA2D3 | c.822C>T p.I274= | Silent (SNP) | VAF 97/734 reads (13%) | catalogued as rs748264157, COSV55567217; called by muse, mutect2, varscan2
- CDH4 | c.1833C>T p.N611= | Silent (SNP) | VAF 121/1085 reads (11%) | catalogued as rs368405359; called by muse, mutect2, varscan2
- CDK5RAP1 | c.189G>A p.P63= | Silent (SNP) | VAF 64/397 reads (16%) | catalogued as rs995701256, COSV100212101; called by muse, mutect2, varscan2
- OPLAH | c.2544C>T p.F848= | Silent (SNP) | VAF 35/263 reads (13%) | catalogued as rs781916565, COSV101470764; called by muse, mutect2, varscan2
- TMEM186 | c.132G>A p.S44= | Silent (SNP) | VAF 50/536 reads (9%) | catalogued as rs149142450; called by muse, mutect2
- CA6 | c.259+2213C>T | Intron (SNP) | VAF 14/178 reads (8%) | catalogued as rs754485409, COSV66263290; called by muse, mutect2
- LINC01565 | n.1108G>A | RNA (SNP) | VAF 36/259 reads (14%) | called by muse, mutect2, varscan2
